Surgical pathology report (de-identified scan), TCGA case TCGA-TT-A6YK, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University of Pennsylvania, specimen TCGA-TT-A6YK-01A (Primary Tumor).

[page 1 of 3]
Age:

Sex: Male

Physician
Copy to:

Surgical Pathology Report

Accession Number	Collection Date/Time	Received Date/Time	Verified Date/Time	Pathologist
------------------	----------------------	--------------------	--------------------	-------------

Clinical Information

Year-old with left paraganglioma, likely pheo
Pre-Operative Diagnosis: Not specified
Post-Operative Diagnosis: Not specified
Operation: Resection of paraganglioma
Specific questions to be answered: None

Specimen:

- 1 Celiac Artery Paraganglioma
- 2 Lymph Node, Celiac Artery

Final Diagnosis

1. Celiac artery paraganglioma, resection:
Paraganglioma, extending multifocally to inked specimen edges, see note.

2. Lymph Node, celiac artery, biopsy:
Fibroadipose tissue with small portion of lymphoid aggregate, nerve and ganglion, no tumor or lymph node seen.

The case material was reviewed and the report verified by:
(Electronic signature)

Verification Date:

Note

The lesion shows focal vascular and capsular invasion, diffuse growth, nuclear atypia, and high cellularity (PASS is 7).

Immunohistochemical stains with adequate controls (see disclaimer) were performed on block 1J for S-100, Chromogranin, and synaptophysin. The tumor cells are strongly positive for Chromogranin and synaptophysin, focally positive for S-100. These findings support the above diagnosis.

Immunostain for SDHB was performed on block 1J for screening possible SDHB germline mutation with adequate controls. Additional molecular/genetic test is recommended for patient with tumor showing negative or weak cytoplasmic SDHB staining pattern if clinically indicated.

The tumor shows negative cytoplasmic SDHB staining.

Name
MRN:

[page 2 of 3]
[REDACTED]
[REDACTED]
Age:

Sex: Male

Print Date:
Date Collected:
Date Received:
Accession No. [REDACTED]
Physician:
Copy to:

Surgical Pathology Report

Accession Number	Collection Date/Time	Received Date/Time	Verified Date/Time	Pathologist
------------------	----------------------	--------------------	--------------------	-------------

Pathologist

Disclaimer:

The above in-vitro IHC tests may have used reagents labeled for IVD (In Vitro Diagnostic Use), IUO (Investigational Use Only) and/or RUO (Research Use Only) and have not been cleared or approved by the U.S Food and Drug Administration. However, the FDA has determined that such clearance or approval is not necessary for ASR class I tests intended to provide pathologists with adjunctive information to assist their morphologic evaluation. The tests using IUO or IUO reagents were developed and their performance characteristics were validated for diagnostic use by the Laboratory of Immunohistochemistry, Anatomic Pathology at the [REDACTED] This laboratory is regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical tests. These Class I ASR tests are not intended to provide diagnostic, prognostic, predictive or therapeutic information that are not directly confirmed by routine histopathologic internal or external control specimens.

Frozen Section Diagnosis

1A: Tumor present, final diagnosis deferred to permanent.

Gross Description

The case is received in 2 fresh containers, each labeled with the patient's name and medical record number.

Specimen 1 is received fresh for frozen section designated "celiac artery paraganglioma" and was described at that time as "one piece of red tan soft tissue weighing 15.1 g and measuring 4.5 x 4.2 x 1.2 cm. The specimen is entirely inked black. The specimen is serially sectioned to reveal a red cut surface. Representative sections frozen as 1A" The specimen which was frozen is received now following formalin fixation and is submitted as 1A. The remaining specimen which was not frozen has been fixed in formalin and appears as previously described and is submitted entirely in 10 cassettes labeled 1A through 1J.

Specimen 2 is designated "celiac artery lymph node", and consists of one brown-red, firm potential lymph node measuring 1.2 x 1.0 x 0.4 cm. The specimen is submitted entirely in one cassette labeled 2A.

Name [REDACTED]
MRN [REDACTED]

[page 3 of 3]
[Redacted]
[Redacted]
[Redacted]

Age: Sex: Male

Print Date:
Date Collected:
Date Received:
Accession No. [Redacted]
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

Accession Number	Collection Date/Time	Received Date/Time	Verified Date/Time	Pathologist
[Redacted]				

SUMMARY OF SECTIONS: 11, multiple, entirely submitted

Pathologist(s)

N/A

Name: [Redacted]
MRN: [Redacted]

Source: NCI Genomic Data Commons file d5dc90a7-d623-4db0-89b1-52a212b0de35 (TCGA-TT-A6YK.EDF00561-9C12-4FD7-B05F-8C71251025B0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).